Somatic mutation profile of tumor specimen TARGET-10-PARDEJ-09A (aliquot TARGET-10-PARDEJ-09A-01D) from TARGET case TARGET-10-PARDEJ, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.4 years (1,245 days).
Specimen TARGET-10-PARDEJ-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9c821f84-1655-4b06-b8ee-8f2510306374.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARDEJ-10A (Blood Derived Normal), aliquot TARGET-10-PARDEJ-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f2f5a40b-d4f7-4474-a06c-392663d8f27f

The open-access MAF lists 19 somatic variants for this specimen: 14 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 14, Silent 5.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 16/74 reads (22%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 14/73 reads (19%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- ANGPT2 | c.416C>T p.T139M | Missense Mutation (SNP) | VAF 39/79 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs201337637; called by muse, mutect2, varscan2
- CTCFL | c.1013A>G p.H338R | Missense Mutation (SNP) | VAF 78/95 reads (82%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs1375256854; called by muse, mutect2, varscan2
- ELMOD1 | c.562G>A p.A188T | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.066); catalogued as rs752553992, COSV56191383; called by muse, mutect2, varscan2
- ERC2 | c.1856G>T p.R619L | Missense Mutation (SNP) | VAF 49/116 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.104); catalogued as COSV55600221; called by muse, mutect2, varscan2
- FGFR1 | c.238C>T p.R80C | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as rs751494167, COSV58343832; called by muse, mutect2, varscan2
- SLC26A5 | c.1021G>A p.V341I | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.039); catalogued as rs150887104; called by muse, mutect2, varscan2
- TRPC7 | c.30G>T p.M10I | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.045); catalogued as COSV61459560, COSV61464566; called by muse, mutect2, varscan2
- CARD17 | c.53G>A p.G18D | Missense Mutation (SNP) | VAF 99/252 reads (39%) | SIFT tolerated (0.42); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- CDHR2 | c.1577C>A p.A526E | Missense Mutation (SNP) | VAF 25/50 reads (50%) | SIFT tolerated (1); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- CYP4F2 | c.7C>A p.Q3K | Missense Mutation (SNP) | VAF 16/28 reads (57%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- FABP9 | c.38C>A p.S13Y | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- HDAC5 | c.2453G>T p.G818V | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2
- FABP9 | c.39C>G p.S13= | Silent (SNP) | VAF 27/89 reads (30%) | called by muse, mutect2, varscan2
- KIAA0319 | c.1368C>A p.G456= | Silent (SNP) | VAF 19/62 reads (31%) | called by muse, mutect2, varscan2
- SORBS2 | c.1803C>T p.D601= | Silent (SNP) | VAF 26/93 reads (28%) | catalogued as rs140964722, COSV52992741; called by muse, mutect2, varscan2
- TTC28 | c.4545C>T p.S1515= | Silent (SNP) | VAF 5/45 reads (11%) | catalogued as rs958508194, COSV67415106; called by muse, mutect2, varscan2
- VWA3B | c.2217C>T p.V739= | Silent (SNP) | VAF 71/154 reads (46%) | catalogued as rs765160787, COSV68242093; called by muse, mutect2, varscan2
